Gene-level copy-number profile of tumor specimen TCGA-CQ-A4CA-01A from TCGA case TCGA-CQ-A4CA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Ventral surface of tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2.
Specimen TCGA-CQ-A4CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.08b369a2-44c2-4258-b6de-b1cb8a64ad5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-A4CA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/08f81cc8-0b0d-4785-9b09-7a7a1c14411f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 2,972; copy number 2: 35,687; copy number 3: 13,634; copy number 4: 5,561; copy number 5: 818; copy number 6: 946; copy number 7: 13; copy number 9: 10; copy number 10: 18; copy number 11: 23; copy number 27: 28; copy number 29: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-A4CA-01A-11D-A253-01): tumor purity 0.29, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–24,088,051, 34 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr21:40,615,378–42,836,477, 53 genes (within-gene range 0–1): DSCAM-IT1, AF064866.1, YRDCP3, AL773573.1, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1, ABCG1, RNA5SP492, TFF3, TFF2, TFF1, TMPRSS3, UBASH3A, RNU6-1149P, RSPH1, SLC37A1, AP001625.3, AP001625.1, AP001625.2, LINC01671, AP001626.1, PDE9A, PDE9A-AS1, LINC01668, AP001628.2, AP001628.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,871 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,455,718–60,868,009, 633 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr6:101,181,257–102,070,083, 1 gene, copy number 6 (within-gene range 3–6): GRIK2.
- chr6:102,078,872–102,079,555, 1 gene, copy number 6: AP002530.1.
- chr11:56,736,316–56,971,979, 13 genes, copy number 7: AP001803.1, OR9G3P, OR9G4, MIR6128, AP001803.10, OR9G2P, OR5G1P, OR5G4P, OR5G5P, OR5G3, LINC02735, FADS2B, OR5AK3P.
- chr11:68,312,591–74,731,426, 212 genes, copy number 6–29 (within-gene range 2–29) (broad region; genes not listed).
- chr11:78,533,176–79,441,030, 9 genes, copy number 9: AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579.
- chr11:98,565,074–102,470,384, 34 genes, copy number 5–27 (within-gene range 2–27): AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123.
- chr12:66,347,431–70,243,379, 78 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr22:26,390,667–31,388,837, 180 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
